Somatic mutation profile of tumor specimen ALCH-B25J-TTP1-A (aliquot ALCH-B25J-TTP1-A-1-0-D-A76N-36) from ALCHEMIST case ALCH-B25J, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.4 years (26,806 days).
Specimen ALCH-B25J-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d82a94ec-119b-4f29-b086-48b3718fc4c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B25J-NB1-A (Blood Derived Normal), aliquot ALCH-B25J-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b13f1f9-9995-44ae-ba4e-a58aa5f7cb10

The open-access MAF lists 371 somatic variants for this specimen: 242 protein-altering or splice-affecting, 78 silent, 51 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 198, Silent 78, Intron 20, Nonsense Mutation 17, RNA 16, Frame Shift Del 11, 3'UTR 7, Splice Site 6, Frame Shift Ins 5, 5'Flank 5, Splice Region 4, 5'UTR 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.1508G>T p.G503V | Missense Mutation (SNP) | VAF 265/553 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397507546, CM086897, CM115675, CM1314033, COSV61004973, COSV61005158, COSV61008174; ClinVar: other / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.467G>C p.R156P | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.876); catalogued as rs371524413, CM984589, COSV52698013, COSV52700732, COSV52710835, COSV52891661; ClinVar: likely pathogenic / uncertain significance; called by muse, varscan2
- TP53 | c.408A>C p.Q136H | Missense Mutation (SNP) | VAF 14/144 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs758781593, CM064342, COSV52979889, COSV52987518, COSV52988005; ClinVar: uncertain significance; called by muse, varscan2
- AMPD2 | c.2242G>A p.V748M | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1476269181, COSV56650389; called by muse, mutect2, varscan2
- APBA2 | c.2229G>T p.Q743H | Missense Mutation (SNP) | VAF 38/228 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1435305426; called by muse, mutect2, varscan2
- CD40LG | c.727G>C p.D243H | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV65698794; called by muse, mutect2, varscan2
- CLCA2 | c.1075G>T p.E359* | Nonsense Mutation (SNP) | VAF 112/463 reads (24%) | catalogued as rs1461498083; called by muse, mutect2, varscan2
- CLNS1A | c.85G>T p.G29W | Missense Mutation (SNP) | VAF 60/230 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.432); catalogued as rs1404216939; called by muse, mutect2, varscan2
- COL9A1 | c.559G>T p.V187L | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as rs773143381, COSV61833606, COSV61835935; called by muse, mutect2, varscan2
- CRACD | c.3475G>T p.A1159S | Missense Mutation (SNP) | VAF 31/211 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as COSV99948939; called by muse, mutect2, varscan2
- CTAGE1 | c.1490C>A p.S497* | Nonsense Mutation (SNP) | VAF 59/314 reads (19%) | catalogued as COSV101194607; called by muse, mutect2, varscan2
- CTNND2 | c.2534C>T p.S845L | Missense Mutation (SNP) | VAF 24/553 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.192); catalogued as COSV100481778; called by muse, mutect2
- DCAF8L2 | c.1763C>T p.T588M | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.762); catalogued as rs780658256, COSV70552185; called by muse, mutect2, varscan2
- DENND4B | c.3794C>T p.A1265V | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.815); catalogued as COSV100768922; called by muse, mutect2, varscan2
- DNAH6 | c.9642G>C p.L3214F | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52887845; called by muse, mutect2
- EDIL3 | c.790G>T p.G264C | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as COSV56918727; called by muse, mutect2
- FAM91A1 | c.1535G>T p.R512L | Missense Mutation (SNP) | VAF 60/270 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.268); catalogued as COSV58236123, COSV58236785; called by muse, mutect2, varscan2
- FLT4 | c.513G>T p.S171= | Splice Region (SNP) | VAF 7/58 reads (12%) | catalogued as COSV56112905; called by muse, mutect2, varscan2
- FRMPD2 | c.1421C>T p.A474V | Missense Mutation (SNP) | VAF 44/197 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1377282422; called by muse, mutect2, varscan2
- GABRB1 | c.500G>A p.R167K | Missense Mutation (SNP) | VAF 36/320 reads (11%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.982); catalogued as COSV54980313; called by muse, mutect2, varscan2
- GABRP | c.585del p.N196Tfs*17 | Frame Shift Del (DEL) | VAF 30/243 reads (12%) | catalogued as rs1156374690, COSV99516752; called by mutect2, pindel, varscan2
- HAO2 | c.1015G>T p.A339S | Missense Mutation (SNP) | VAF 78/304 reads (26%) | SIFT tolerated (0.73); PolyPhen benign (0.014); catalogued as COSV58038131, COSV58039053; called by muse, varscan2
- JAK2 | c.2033A>T p.N678I | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67689792; called by muse, mutect2, varscan2
- JMJD1C | c.206G>T p.R69L | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV101232425, COSV104434158; called by muse, mutect2, varscan2
- JRK | c.568G>A p.G190S | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as rs370117344; called by muse, mutect2, varscan2
- KATNAL1 | c.943C>T p.R315* | Nonsense Mutation (SNP) | VAF 27/233 reads (12%) | catalogued as rs1265045426, COSV66065176; called by muse, mutect2, varscan2
- KCNC4 | c.8G>C p.S3T | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.973); catalogued as rs1166714383; called by muse, mutect2, varscan2
- KRTAP5-5 | c.647G>T p.S216I | Missense Mutation (SNP) | VAF 71/272 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.36); catalogued as rs754218603; called by muse, mutect2, varscan2
- LGI3 | c.941G>C p.R314P | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as COSV60443107, COSV60443550; called by muse, mutect2, varscan2
- LINS1 | c.2174G>A p.R725H | Missense Mutation (SNP) | VAF 59/349 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs150007988; called by muse, mutect2, varscan2
- LONRF2 | c.2213G>C p.R738P | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs775108359; called by muse, mutect2, varscan2
- MAFA | c.995C>T p.P332L | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs776653758; called by muse, mutect2, varscan2
- MAN2C1 | c.700G>T p.A234S | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.346); catalogued as rs1567284232, COSV51228395; called by muse, mutect2, varscan2
- MAP1B | c.2443G>A p.A815T | Missense Mutation (SNP) | VAF 30/262 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV57106774; called by muse, mutect2, varscan2
- MCF2L2 | c.2342A>T p.D781V | Missense Mutation (SNP) | VAF 32/287 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV61052631; called by muse, mutect2
- MED23 | c.3154G>A p.A1052T | Missense Mutation (SNP) | VAF 49/354 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs151337645; called by muse, mutect2, varscan2
- MLN | c.68C>A p.T23K | Missense Mutation (SNP) | VAF 49/233 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.442); catalogued as rs746105078, COSV99803045; called by muse, mutect2, varscan2
- MSR1 | c.1167G>T p.R389S | Missense Mutation (SNP) | VAF 124/388 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1164354547; called by muse, mutect2, varscan2
- MUC16 | c.25127C>A p.P8376H | Missense Mutation (SNP) | VAF 54/105 reads (51%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.046); catalogued as COSV101198074; called by muse, mutect2, varscan2
- MYH14 | c.3368G>A p.R1123Q | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as rs760554160; called by muse, mutect2, varscan2
- MYH7 | c.3818T>A p.L1273H | Missense Mutation (SNP) | VAF 88/516 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as CM1411011; called by muse, mutect2, varscan2
- NEU4 | c.39C>G p.F13L (on ENST00000391969 / NM_001167602.3; = p.F25L on NM_080741.4) | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV57990448; called by muse, mutect2, varscan2
- NEU4 | c.40G>A p.E14K (on ENST00000391969 / NM_001167602.3; = p.E26K on NM_080741.4) | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs200948491, COSV57989900; called by muse, mutect2, varscan2
- OR11H12 | c.803G>A p.S268N | Missense Mutation (SNP) | VAF 25/244 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as rs1381280746; called by mutect2, varscan2
- OR5H14 | c.728C>A p.A243D | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs772736386, COSV71194251; called by muse, mutect2, varscan2
- OR5R1 | c.360C>A p.Y120* | Nonsense Mutation (SNP) | VAF 32/166 reads (19%) | catalogued as COSV56571696; called by muse, mutect2, varscan2
- OR8K3 | c.775G>T p.V259L | Missense Mutation (SNP) | VAF 34/257 reads (13%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.017); catalogued as rs761417566; called by muse, mutect2, varscan2
- PAPPA2 | c.4079C>A p.S1360Y | Missense Mutation (SNP) | VAF 26/690 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.127); catalogued as COSV62795455; called by muse, mutect2
- PCDHB8 | c.1445G>T p.G482V | Missense Mutation (SNP) | VAF 74/729 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as rs1467234607; called by muse, mutect2, varscan2
- PCDHGA8 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.052); catalogued as rs762034418; called by muse, mutect2, varscan2
- PCDHGC5 | c.1861G>T p.V621L | Missense Mutation (SNP) | VAF 6/119 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV52745850; called by muse, mutect2
- PDZD8 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs7081659; called by muse, mutect2, varscan2
- PIRT | c.63C>A p.D21E | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.734); catalogued as rs773101677; called by muse, mutect2
- PLK2 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 28/283 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs55768901, COSV57108553; called by muse, mutect2
- PREX1 | c.2817G>T p.E939D | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as COSV64255661; called by muse, mutect2, varscan2
- PRUNE2 | c.422G>T p.R141L | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.069); catalogued as rs374764527; called by muse, mutect2
- PTDSS1 | c.674G>T p.C225F | Missense Mutation (SNP) | VAF 56/322 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61266483; called by muse, mutect2, varscan2
- PTPRF | c.2588C>T p.A863V | Missense Mutation (SNP) | VAF 32/255 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.081); catalogued as rs144536559; called by muse, mutect2, varscan2
- RBPJ | c.418A>T p.M140L | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.026); catalogued as COSV60755000; called by muse, mutect2, varscan2
- ROBO3 | c.3922G>A p.V1308M | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs752717878, COSV60624157; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- S100B | c.40G>T p.V14F | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99388288; called by muse, mutect2, varscan2
- SH2B2 | c.1676G>T p.R559L | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT tolerated (0.59); PolyPhen benign (0.031); catalogued as rs1554558189, COSV100159204; called by muse, mutect2, varscan2
- SHOX | c.331G>C p.G111R | Missense Mutation (SNP) | VAF 96/415 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as rs764179159; called by muse, mutect2, varscan2
- SLC26A7 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV104372275; called by muse, mutect2, varscan2
- SLC34A3 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs750770872; called by muse, mutect2, varscan2
- SLC5A10 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.327); catalogued as rs547915569, COSV100525109; called by muse, mutect2, varscan2
- SMCHD1 | c.4895A>G p.Q1632R | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV55264870; called by muse, mutect2, varscan2
- STAM | c.514G>T p.E172* | Nonsense Mutation (SNP) | VAF 25/182 reads (14%) | catalogued as COSV101092428; called by muse, varscan2
- STK11 | c.465-3C>G | Splice Region (SNP) | VAF 27/59 reads (46%) | catalogued as COSV100480651; called by muse, mutect2, varscan2
- TCF4 | c.1318G>A p.G440S | Missense Mutation (SNP) | VAF 38/394 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as rs759754956; ClinVar: benign; called by muse, mutect2, varscan2
- TEFM | c.293A>G p.N98S | Missense Mutation (SNP) | VAF 96/261 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.166); catalogued as rs754782248; called by muse, mutect2, varscan2
- TENM1 | c.947G>T p.W316L | Missense Mutation (SNP) | VAF 19/225 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100950520; called by muse, mutect2
- THSD7A | c.1332G>C p.Q444H | Missense Mutation (SNP) | VAF 139/357 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.704); catalogued as rs777352772; called by muse, mutect2, varscan2
- TTN | c.81505C>A p.L27169M (on ENST00000591111; = p.L19745M on NM_003319.4) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | PolyPhen possibly damaging (0.9); catalogued as rs1559279633; called by muse, mutect2, varscan2
- TYK2 | c.1870G>A p.E624K | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.125); catalogued as rs765740248; called by muse, mutect2, varscan2
- USP6 | c.691G>T p.V231F | Missense Mutation (SNP) | VAF 104/250 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.28); catalogued as COSV51475569; called by muse, mutect2, varscan2
- VTN | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 54/206 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs781937745, COSV99412034; called by muse, mutect2, varscan2
- WDR36 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 28/219 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs147193465; called by muse, mutect2, varscan2
- ZDBF2 | c.5068C>T p.R1690W | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs763893380, COSV65630000; called by muse, mutect2, varscan2
- ZFHX4 | c.7553C>A p.A2518D | Missense Mutation (SNP) | VAF 67/330 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV51475350; called by muse, mutect2, varscan2
- ZNF839 | c.226A>G p.R76G (on ENST00000558850 / NM_001267827.1; = p.R192G on NM_018335.5) | Missense Mutation (SNP) | VAF 34/324 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1368179826; called by muse, mutect2, varscan2
- ZSCAN5C | c.1471C>G p.R491G | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1466978397, COSV66185965; called by muse, mutect2
- A2ML1 | c.691dup p.T231Nfs*13 | Frame Shift Ins (INS) | VAF 91/272 reads (33%) | called by mutect2, pindel, varscan2
- ABCA9 | c.1400G>T p.C467F | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCG5 | c.1384C>A p.Q462K | Missense Mutation (SNP) | VAF 88/466 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADAM12 | c.148G>A p.G50R | Missense Mutation (SNP) | VAF 24/189 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ADGRE2 | c.1318G>T p.G440C | Missense Mutation (SNP) | VAF 78/282 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- AK2 | c.136G>T p.E46* (on ENST00000354858; = p.E88* on NM_001625.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 102/355 reads (29%) | called by muse, mutect2, varscan2
- ANKRD30B | c.3376C>A p.L1126I | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2
- ATCAY | c.17C>A p.A6D | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- ATP2B3 | c.1363del p.V455Cfs*29 | Frame Shift Del (DEL) | VAF 16/133 reads (12%) | called by mutect2, pindel*
- ATP5MGL | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 55/389 reads (14%) | called by muse, mutect2, varscan2
- ATRNL1 | c.1261T>G p.L421V | Missense Mutation (SNP) | VAF 7/200 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.036); called by muse, mutect2
- BABAM2 | c.992A>G p.Y331C | Missense Mutation (SNP) | VAF 59/255 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BAK1 | c.439C>A p.L147M | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- BASP1 | c.48C>A p.D16E | Missense Mutation (SNP) | VAF 19/536 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.921); called by muse, mutect2
- BMP3 | c.349A>T p.N117Y | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C1QTNF1 | c.190C>A p.Q64K | Missense Mutation (SNP) | VAF 22/231 reads (10%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.011); called by muse, varscan2
- C7 | c.332A>G p.E111G | Missense Mutation (SNP) | VAF 323/531 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- CASS4 | c.472C>A p.L158I | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CCND3 | c.57del p.R20Gfs*63 | Frame Shift Del (DEL) | VAF 11/47 reads (23%) | called by mutect2, pindel*, varscan2
- CCR1 | c.762dup p.Y255Lfs*18 | Frame Shift Ins (INS) | VAF 36/151 reads (24%) | called by mutect2, pindel, varscan2
- CEP170B | c.1487G>T p.R496L (on ENST00000453495; = p.R425L on NM_015005.3) | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CFAP47 | c.8246C>A p.T2749K | Missense Mutation (SNP) | VAF 31/177 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CFAP52 | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 30/379 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); called by muse, mutect2
- CHRM2 | c.267G>T p.W89C | Missense Mutation (SNP) | VAF 85/735 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLCN7 | c.1517G>T p.G506V | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLCN7 | c.538G>T p.A180S | Missense Mutation (SNP) | VAF 49/281 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- CPN1 | c.127C>A p.P43T | Missense Mutation (SNP) | VAF 50/320 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CREBBP | c.2002A>T p.K668* | Nonsense Mutation (SNP) | VAF 34/242 reads (14%) | called by muse, mutect2, varscan2
- CSTB | c.46A>T p.T16S | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.609); called by muse, mutect2, varscan2
- DDX19A | c.1064A>G p.E355G | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- DDX19A | c.1065A>C p.E355D | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- DENND4B | c.1318del p.L440Sfs*4 | Frame Shift Del (DEL) | VAF 4/25 reads (16%) | called by mutect2, pindel*, varscan2
- DNAH1 | c.7189dup p.E2397Gfs*58 | Frame Shift Ins (INS) | VAF 13/73 reads (18%) | called by mutect2, pindel, varscan2
- DOCK4 | c.3559-1G>C p.X1187_splice | Splice Site (SNP) | VAF 22/166 reads (13%) | called by muse, mutect2, varscan2
- EEF1A1 | c.340C>G p.L114V | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EHMT2 | c.1546del p.A516Pfs*12 | Frame Shift Del (DEL) | VAF 37/152 reads (24%) | called by mutect2, pindel, varscan2
- EPHA10 | c.2955G>T p.E985D | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FLG2 | c.4319C>A p.P1440Q | Missense Mutation (SNP) | VAF 132/510 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- FLNA | c.1499C>A p.T500K | Missense Mutation (SNP) | VAF 34/242 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- FSD1 | c.149A>T p.E50V | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- GABRG3 | c.1211G>T p.C404F | Missense Mutation (SNP) | VAF 64/320 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- GFI1B | c.529G>T p.G177W | Missense Mutation (SNP) | VAF 68/221 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GK | c.1112C>A p.S371* (on ENST00000427190 / NM_001205019.2; = p.S365* on NM_000167.6) | Nonsense Mutation (SNP) | VAF 12/217 reads (6%) | called by muse, mutect2
- GMPR | c.127C>T p.Q43* | Nonsense Mutation (SNP) | VAF 30/346 reads (9%) | called by muse, mutect2
- GNAT3 | c.601G>A p.V201I | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- GOLM1 | c.14G>T p.G5V | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- GPC3 | c.152G>T p.W51L | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- GRIK4 | c.598C>G p.P200A | Missense Mutation (SNP) | VAF 32/277 reads (12%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- HDAC8 | c.344T>C p.I115T | Missense Mutation (SNP) | VAF 32/283 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- HIF1AN | c.985G>T p.A329S | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- HOXD11 | c.470C>A p.P157H | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- IFTAP | c.167del p.G56Efs*43 | Frame Shift Del (DEL) | VAF 24/75 reads (32%) | called by mutect2, pindel, varscan2
- IGSF1 | c.14G>A p.R5K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.007); called by muse, mutect2
- IL13RA1 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- IMPACT | c.637G>T p.A213S | Missense Mutation (SNP) | VAF 31/187 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- ING3 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 28/343 reads (8%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.956); called by muse, mutect2
- IQSEC2 | c.173A>C p.N58T | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- KCNC2 | c.239G>T p.G80V | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- KCNMB1 | c.10A>T p.K4* | Nonsense Mutation (SNP) | VAF 17/110 reads (15%) | called by muse, mutect2, varscan2
- KLHL4 | c.461G>T p.R154I | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRT12 | c.798C>G p.N266K | Missense Mutation (SNP) | VAF 46/477 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- LAMC3 | c.3788C>A p.S1263Y | Missense Mutation (SNP) | VAF 89/248 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- MAGEB5 | c.177G>T p.Q59H | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- MAGI3 | c.4387A>T p.K1463* | Nonsense Mutation (SNP) | VAF 12/125 reads (10%) | called by muse, mutect2
- MAGT1 | c.679G>C p.V227L (on ENST00000618282 / NM_001367916.1; = p.V259L on NM_032121.5) | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- MCF2L2 | c.2341G>T p.D781Y | Missense Mutation (SNP) | VAF 32/290 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); called by muse, mutect2
- MORC4 | c.1544A>C p.Q515P | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MORC4 | c.1210dup p.T404Nfs*5 | Frame Shift Ins (INS) | VAF 40/369 reads (11%) | called by mutect2, pindel, varscan2
- MUC16 | c.43390C>A p.L14464M | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MUC16 | c.10597G>A p.A3533T | Missense Mutation (SNP) | VAF 39/277 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MUC4 | c.12788C>A p.P4263Q | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.031); called by muse, varscan2
- MX2 | c.1741C>A p.Q581K | Missense Mutation (SNP) | VAF 63/241 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYH1 | c.5308G>T p.A1770S | Missense Mutation (SNP) | VAF 110/358 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- MYH2 | c.3440G>T p.R1147L | Missense Mutation (SNP) | VAF 210/554 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAGA | c.56A>T p.D19V | Missense Mutation (SNP) | VAF 48/182 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- NBL1 | c.285G>T p.V95= | Splice Region (SNP) | VAF 12/35 reads (34%) | called by muse, mutect2, varscan2
- NBPF12 | c.1460G>T p.G487V | Missense Mutation (SNP) | VAF 132/691 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NCAM2 | c.1825T>A p.F609I | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- NCR3LG1 | c.843G>C p.L281F | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- NELL1 | c.179T>A p.F60Y | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- NEU4 | c.617G>T p.G206V (on ENST00000391969 / NM_001167602.3; = p.G218V on NM_080741.4) | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NEXN | c.556A>T p.K186* | Nonsense Mutation (SNP) | VAF 9/88 reads (10%) | called by muse, mutect2, varscan2
- NKX6-3 | c.346G>T p.G116C | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.586); called by muse, mutect2, varscan2
- NLGN1 | c.64C>T p.H22Y | Missense Mutation (SNP) | VAF 35/200 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- NLGN4X | c.2015C>A p.S672Y | Missense Mutation (SNP) | VAF 125/435 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- NLRP14 | c.2216G>T p.S739I | Missense Mutation (SNP) | VAF 55/276 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- NLRP7 | c.1322A>C p.Q441P | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- NOTCH3 | c.1314del p.C440Afs*11 | Frame Shift Del (DEL) | VAF 52/136 reads (38%) | called by mutect2, pindel, varscan2
- NPHP1 | c.1589G>T p.R530I (on ENST00000393272 / NM_207181.4; = p.R531I on NM_000272.5) | Missense Mutation (SNP) | VAF 34/292 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR10G7 | c.290T>A p.V97E | Missense Mutation (SNP) | VAF 87/487 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- OR2G2 | c.484C>A p.Q162K | Missense Mutation (SNP) | VAF 31/167 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- OR4C13 | c.188A>G p.Y63C | Missense Mutation (SNP) | VAF 54/234 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- OR51S1 | c.686G>T p.G229V | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCK1 | c.938C>A p.A313D | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PDGFRB | c.974T>C p.L325P | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.248); called by muse, varscan2
- PGGHG | c.2028G>T p.K676N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PIP4P2 | c.383G>T p.G128V | Missense Mutation (SNP) | VAF 66/279 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- PKD1L1 | c.4825G>T p.V1609F | Missense Mutation (SNP) | VAF 36/432 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.226); called by muse, mutect2
- PLXNB3 | c.4168C>A p.L1390M | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP4C | c.99A>T p.R33S | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- PRAMEF18 | c.866+1G>A p.X289_splice | Splice Site (SNP) | VAF 39/244 reads (16%) | called by muse, mutect2, varscan2
- PTCHD3 | c.1027C>T p.L343F | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by mutect2, varscan2
- PTGS1 | c.714G>T p.E238D | Missense Mutation (SNP) | VAF 60/337 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- QRSL1 | c.153A>T p.Q51H | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.468); called by muse, varscan2
- RBM10 | c.1479del p.M493Ifs*211 | Frame Shift Del (DEL) | VAF 71/259 reads (27%) | called by mutect2, pindel, varscan2
- RNF187 | c.170G>T p.W57L | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- RYR2 | c.830T>C p.L277P | Missense Mutation (SNP) | VAF 36/262 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- RYR2 | c.2255A>G p.D752G | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.82); PolyPhen benign (0.01); called by muse, varscan2
- SAPCD2 | c.131_144del p.R44Pfs*118 | Frame Shift Del (DEL) | VAF 10/100 reads (10%) | called by mutect2, pindel
- SASH3 | c.572A>G p.H191R | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCRIB | c.662G>T p.R221L | Missense Mutation (SNP) | VAF 42/196 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SEL1L | c.2046+1G>C p.X682_splice | Splice Site (SNP) | VAF 4/59 reads (7%) | called by muse, mutect2
- SEMA6A | c.1655C>G p.T552S | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- SERPINA6 | c.1088C>A p.S363Y | Missense Mutation (SNP) | VAF 34/262 reads (13%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- SLC12A2 | c.172G>T p.D58Y | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.101); called by muse, varscan2
- SLC4A1 | c.675G>C p.E225D | Missense Mutation (SNP) | VAF 17/332 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); called by muse, mutect2
- SLC4A10 | c.1166G>T p.R389I (on ENST00000446997 / NM_001354461.2; = p.R359I on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/238 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SMCHD1 | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.477); called by muse, mutect2
- SP9 | c.374A>T p.Q125L | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- SPATA22 | c.932G>T p.R311L | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.327); called by mutect2, varscan2
- SPTBN2 | c.309G>T p.L103= | Splice Region (SNP) | VAF 84/390 reads (22%) | called by muse, mutect2, varscan2
- STEAP2 | c.581C>A p.S194Y | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.172); called by muse, mutect2
- TAF1 | c.103G>T p.E35* | Nonsense Mutation (SNP) | VAF 8/83 reads (10%) | called by muse, mutect2, varscan2
- TBC1D9B | c.3220A>T p.R1074W (on ENST00000356834 / NM_198868.3; = p.R1057W on NM_015043.4) | Missense Mutation (SNP) | VAF 31/226 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- TBX18 | c.985del p.R329Efs*27 | Frame Shift Del (DEL) | VAF 73/310 reads (24%) | called by mutect2, pindel, varscan2
- TDRKH | c.1434+1G>A p.X478_splice | Splice Site (SNP) | VAF 13/86 reads (15%) | called by muse, varscan2
- TEX43 | c.379C>T p.H127Y | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- TF | c.1003G>C p.G335R | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- THBS2 | c.3151G>A p.E1051K | Missense Mutation (SNP) | VAF 58/358 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- TMEM196 | c.64G>T p.G22W | Missense Mutation (SNP) | VAF 33/216 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMEM272 | c.98C>G p.P33R | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- TNFAIP2 | c.1033G>T p.E345* | Nonsense Mutation (SNP) | VAF 76/210 reads (36%) | called by muse, mutect2, varscan2
- TPRX1 | c.484C>A p.P162T | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRABD2B | c.180dup p.Y61Lfs*19 | Frame Shift Ins (INS) | VAF 56/212 reads (26%) | called by mutect2, pindel, varscan2
- TRAK1 | c.772G>T p.D258Y (on ENST00000327628 / NM_001349247.2; = p.D200Y on NM_014965.5) | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- TRO | c.2354C>A p.S785Y | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- TSGA10IP | c.1654C>A p.P552T | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- TSPAN18 | c.251T>A p.L84Q | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTC14 | c.1876A>T p.R626* | Nonsense Mutation (SNP) | VAF 14/134 reads (10%) | called by muse, mutect2, varscan2
- TTC3 | c.1388A>T p.D463V | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- UMOD | c.1529C>A p.P510H | Missense Mutation (SNP) | VAF 93/237 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VWCE | c.424+1G>T p.X142_splice | Splice Site (SNP) | VAF 11/58 reads (19%) | called by muse, mutect2, varscan2
- WASHC2A | c.545G>T p.R182L | Missense Mutation (SNP) | VAF 58/396 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDFY4 | c.1079G>A p.S360N | Missense Mutation (SNP) | VAF 31/160 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- WDFY4 | c.4328T>A p.V1443E | Missense Mutation (SNP) | VAF 43/200 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- WDR70 | c.1896G>T p.M632I | Missense Mutation (SNP) | VAF 195/301 reads (65%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- XRN2 | c.859-2A>T p.X287_splice | Splice Site (SNP) | VAF 14/86 reads (16%) | called by muse, mutect2, varscan2
- ZBTB33 | c.958A>G p.I320V | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZBTB42 | c.744_746dup p.P250dup | In Frame Ins (INS) | VAF 5/32 reads (16%) | called by mutect2, pindel
- ZFPM1 | c.677G>A p.G226E | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ZMYM3 | c.1936C>T p.L646F | Missense Mutation (SNP) | VAF 37/243 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- ZNF135 | c.1763G>T p.S588I (on ENST00000313434 / NM_001289401.2; = p.S600I on NM_003436.4) | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ZNF217 | c.2921G>T p.S974I | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- ZNF280B | c.77A>T p.E26V | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- ZNF335 | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- ZNF33B | c.759del p.R254Efs*33 | Frame Shift Del (DEL) | VAF 19/144 reads (13%) | called by mutect2, pindel, varscan2
- ZNF462 | c.640G>T p.D214Y | Missense Mutation (SNP) | VAF 71/152 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.467); called by muse, varscan2
- ZNF716 | c.34G>T p.E12* | Nonsense Mutation (SNP) | VAF 47/436 reads (11%) | called by muse, mutect2, varscan2
- ZNF790 | c.1589G>C p.G530A | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZNF831 | c.2507C>A p.P836Q | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- ACSF2 | c.1543C>A p.R515= | Silent (SNP) | VAF 37/327 reads (11%) | catalogued as rs765996539; called by muse, mutect2, varscan2
- AOX1 | c.1929A>C p.T643= | Silent (SNP) | VAF 45/276 reads (16%) | called by muse, mutect2, varscan2
- APOD | c.27C>T p.S9= | Silent (SNP) | VAF 43/286 reads (15%) | catalogued as rs923850853; called by muse, mutect2, varscan2
- ATP6V0A4 | c.2418G>T p.L806= | Silent (SNP) | VAF 46/455 reads (10%) | called by muse, mutect2, varscan2
- AWAT1 | c.801C>T p.L267= | Silent (SNP) | VAF 38/291 reads (13%) | catalogued as COSV65738895; called by muse, mutect2, varscan2
- BDH1 | c.6G>T p.L2= | Silent (SNP) | VAF 34/157 reads (22%) | called by muse, mutect2, varscan2
- BOD1L1 | c.996A>G p.G332= | Silent (SNP) | VAF 54/395 reads (14%) | called by muse, mutect2, varscan2
- BPIFB4 | c.573C>T p.L191= | Silent (SNP) | VAF 19/166 reads (11%) | catalogued as rs148665748; called by muse, mutect2
- C10orf90 | c.204C>A p.A68= | Silent (SNP) | VAF 33/232 reads (14%) | called by muse, mutect2, varscan2
- C1orf167 | c.2007T>A p.G669= | Silent (SNP) | VAF 65/220 reads (30%) | called by muse, mutect2, varscan2
- C1orf94 | c.240A>T p.S80= | Silent (SNP) | VAF 14/188 reads (7%) | called by muse, mutect2
- CELSR3 | c.3375G>A p.T1125= | Silent (SNP) | VAF 14/132 reads (11%) | catalogued as rs200128579, COSV50922765; called by muse, mutect2, varscan2
- CENPC | c.423A>T p.I141= | Silent (SNP) | VAF 33/163 reads (20%) | called by muse, mutect2, varscan2
- CFAP44 | c.3537C>A p.A1179= | Silent (SNP) | VAF 40/240 reads (17%) | called by muse, mutect2, varscan2
- CHL1 | c.1893C>A p.T631= (on ENST00000397491 / NM_001253387.1; = p.T647= on NM_006614.4) | Silent (SNP) | VAF 28/296 reads (9%) | called by muse, mutect2
- CHRM3 | c.538C>A p.R180= | Silent (SNP) | VAF 36/168 reads (21%) | catalogued as COSV55109951, COSV99699460; called by muse, mutect2, varscan2
- CORIN | c.723C>T p.S241= | Silent (SNP) | VAF 34/318 reads (11%) | called by muse, mutect2, varscan2
- CSMD3 | c.10098A>G p.T3366= (on ENST00000297405 / NM_001363185.1; = p.T3197= on NM_052900.3) | Silent (SNP) | VAF 120/611 reads (20%) | called by muse, mutect2, varscan2
- DDB1 | c.2562G>T p.S854= | Silent (SNP) | VAF 17/64 reads (27%) | called by mutect2, varscan2
- FDXR | c.1143C>T p.P381= (on ENST00000293195 / NM_024417.5; = p.P387= on NM_004110.6) | Silent (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- GALR2 | c.732C>A p.L244= | Silent (SNP) | VAF 11/96 reads (11%) | called by muse, mutect2, varscan2
- GIGYF1 | c.174A>G p.E58= | Silent (SNP) | VAF 23/174 reads (13%) | called by muse, mutect2, varscan2
- GPR75 | c.651G>C p.V217= | Silent (SNP) | VAF 29/148 reads (20%) | called by muse, mutect2, varscan2
- HCN4 | c.2508G>A p.A836= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs766293595, COSV56083162; ClinVar: likely benign; called by muse, mutect2, varscan2
- HIRA | c.159C>T p.D53= | Silent (SNP) | VAF 13/157 reads (8%) | catalogued as rs767322263; called by muse, mutect2
- HIVEP2 | c.1302G>A p.P434= | Silent (SNP) | VAF 31/177 reads (18%) | catalogued as rs944341938; called by muse, mutect2, varscan2
- IGLV8-61 | c.249G>A p.G83= | Silent (SNP) | VAF 42/319 reads (13%) | catalogued as rs1412480210; called by muse, mutect2, varscan2
- IQSEC1 | c.1065G>T p.T355= | Silent (SNP) | VAF 39/110 reads (35%) | called by muse, mutect2, varscan2
- KCP | c.4113C>A p.A1371= (on ENST00000620378; = p.A1495= on NM_001366122.1) | Silent (SNP) | VAF 57/467 reads (12%) | called by muse, mutect2, varscan2
- KEAP1 | c.1629G>T p.T543= | Silent (SNP) | VAF 64/174 reads (37%) | called by muse, mutect2, varscan2
- LRRC7 | c.324T>A p.A108= (on ENST00000651989 / NM_001370785.2; = p.A75= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 25/134 reads (19%) | called by muse, varscan2
- LSAMP | c.393A>C p.P131= | Silent (SNP) | VAF 27/218 reads (12%) | called by muse, mutect2, varscan2
- MAGEB6 | c.1207T>C p.L403= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as rs779474748; called by muse, mutect2, varscan2
- MAP3K19 | c.3960G>A p.K1320= | Silent (SNP) | VAF 20/182 reads (11%) | called by muse, mutect2
- MAP3K9 | c.1926G>A p.L642= | Silent (SNP) | VAF 50/111 reads (45%) | called by muse, mutect2, varscan2
- MED17 | c.216C>T p.G72= | Silent (SNP) | VAF 89/236 reads (38%) | called by muse, mutect2, varscan2
- MGAT4D | c.205C>A p.R69= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV72331975; called by muse, mutect2, varscan2
- MGAT5B | c.1110C>G p.G370= | Silent (SNP) | VAF 11/163 reads (7%) | called by muse, mutect2
- MUC16 | c.43389C>A p.L14463= | Silent (SNP) | VAF 42/129 reads (33%) | called by muse, mutect2, varscan2
- MUC6 | c.3633C>T p.P1211= | Silent (SNP) | VAF 32/172 reads (19%) | catalogued as rs1388399902; called by muse, mutect2, varscan2
- MUC7 | c.873A>T p.T291= | Silent (SNP) | VAF 39/334 reads (12%) | called by muse, mutect2, varscan2
- NPHS1 | c.99C>T p.G33= | Silent (SNP) | VAF 45/273 reads (16%) | called by muse, mutect2, varscan2
- NPHS2 | c.165G>A p.G55= | Silent (SNP) | VAF 25/137 reads (18%) | catalogued as CM161452; called by muse, mutect2, varscan2
- NRXN2 | c.3175C>A p.R1059= | Silent (SNP) | VAF 74/322 reads (23%) | catalogued as COSV55454740; called by muse, mutect2, varscan2
- NSFL1C | c.111G>A p.A37= | Silent (SNP) | VAF 47/151 reads (31%) | catalogued as rs775040874, COSV53795520, COSV99401546; called by muse, mutect2, varscan2
- OAS3 | c.675G>T p.P225= | Silent (SNP) | VAF 80/163 reads (49%) | called by muse, mutect2, varscan2
- OPA3 | c.279C>G p.G93= | Silent (SNP) | VAF 59/174 reads (34%) | called by muse, mutect2, varscan2
- OPCML | c.744A>T p.A248= | Silent (SNP) | VAF 50/243 reads (21%) | called by muse, varscan2
- OR10G3 | c.573T>A p.A191= | Silent (SNP) | VAF 49/166 reads (30%) | called by muse, mutect2, varscan2
- OR4C13 | c.705C>A p.L235= | Silent (SNP) | VAF 60/248 reads (24%) | catalogued as COSV99081855; called by muse, mutect2, varscan2
- OR5L1 | c.102C>A p.I34= | Silent (SNP) | VAF 44/243 reads (18%) | called by muse, mutect2, varscan2
- PADI6 | c.1467C>A p.P489= | Silent (SNP) | VAF 44/128 reads (34%) | catalogued as COSV61884570; called by muse, mutect2, varscan2
- PCDHGA8 | c.1854G>T p.S618= | Silent (SNP) | VAF 27/140 reads (19%) | catalogued as COSV53908996; called by muse, mutect2, varscan2
- PKLR | c.1275C>A p.A425= | Silent (SNP) | VAF 47/175 reads (27%) | called by muse, mutect2, varscan2
- PLAC1 | c.366A>C p.P122= | Silent (SNP) | VAF 20/192 reads (10%) | called by muse, mutect2, varscan2
- PMFBP1 | c.1911G>T p.L637= (on ENST00000537465; = p.L632= on NM_031293.3) | Silent (SNP) | VAF 78/216 reads (36%) | called by muse, mutect2, varscan2
- PRIMPOL | c.1368C>T p.F456= | Silent (SNP) | VAF 12/111 reads (11%) | called by muse, mutect2, varscan2
- PRUNE1 | c.843C>T p.V281= | Silent (SNP) | VAF 122/381 reads (32%) | called by muse, mutect2, varscan2
- RP1L1 | c.5133C>A p.G1711= | Silent (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2, varscan2
- RPA4 | c.672G>T p.R224= | Silent (SNP) | VAF 111/389 reads (29%) | called by muse, mutect2, varscan2
- RPS6KB1 | c.171G>T p.G57= | Silent (SNP) | VAF 32/114 reads (28%) | called by muse, mutect2, varscan2
- RYR2 | c.5271C>A p.L1757= | Silent (SNP) | VAF 30/150 reads (20%) | catalogued as rs1267389337, COSV63684757; called by muse, mutect2, varscan2
- SH2B2 | c.1677G>T p.R559= | Silent (SNP) | VAF 42/84 reads (50%) | called by muse, mutect2, varscan2
- SIX5 | c.1011C>T p.L337= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as rs774389197; called by muse, mutect2, varscan2
- SNX31 | c.996G>A p.T332= | Silent (SNP) | VAF 42/276 reads (15%) | catalogued as rs761345872; called by muse, mutect2, varscan2
- SORCS3 | c.1968C>T p.D656= | Silent (SNP) | VAF 20/168 reads (12%) | catalogued as rs372850065; called by muse, mutect2, varscan2
- TBC1D2B | c.1620T>C p.S540= | Silent (SNP) | VAF 11/62 reads (18%) | called by muse, mutect2, varscan2
- TDRD15 | c.2505T>C p.Y835= | Silent (SNP) | VAF 36/161 reads (22%) | called by muse, mutect2, varscan2
- TEAD1 | c.390C>T p.I130= | Silent (SNP) | VAF 113/487 reads (23%) | catalogued as rs548044773, COSV57564036; called by muse, mutect2, varscan2
- TEX11 | c.1915C>A p.R639= (on ENST00000344304; = p.R624= on NM_031276.3) | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as COSV60227148; called by muse, mutect2, varscan2
- UNC5C | c.912G>T p.V304= | Silent (SNP) | VAF 121/482 reads (25%) | catalogued as COSV71660789; called by muse, mutect2, varscan2
- USH2A | c.8904C>T p.T2968= | Silent (SNP) | VAF 114/537 reads (21%) | catalogued as COSV56443178; called by muse, mutect2, varscan2
- VWA2 | c.1335A>T p.P445= | Silent (SNP) | VAF 10/48 reads (21%) | called by muse, mutect2, varscan2
- WDR53 | c.246C>T p.S82= | Silent (SNP) | VAF 38/283 reads (13%) | called by muse, mutect2, varscan2
- ZFR2 | c.1209C>T p.C403= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs561205889; called by muse, mutect2
- ZNF585A | c.975C>G p.P325= (on ENST00000292841 / NM_001288800.2; = p.P270= on NM_152655.3) | Silent (SNP) | VAF 28/281 reads (10%) | called by muse, mutect2, varscan2
- ZNF711 | c.1800C>G p.T600= | Silent (SNP) | VAF 39/327 reads (12%) | called by muse, mutect2, varscan2
- ZNF831 | c.747T>A p.G249= | Silent (SNP) | VAF 11/41 reads (27%) | called by muse, mutect2
- ABI3BP | c.1577-14420C>A | Intron (SNP) | VAF 65/315 reads (21%) | catalogued as rs924075949; called by muse, mutect2, varscan2
- AC007907.1 | n.327A>T | RNA (SNP) | VAF 20/109 reads (18%) | called by muse, mutect2, varscan2
- AC008080.1 | n.462A>T | RNA (SNP) | VAF 30/309 reads (10%) | called by muse, mutect2
- AC008080.1 | n.463A>T | RNA (SNP) | VAF 27/303 reads (9%) | called by muse, mutect2
- AC073648.1 | n.331C>A | RNA (SNP) | VAF 33/317 reads (10%) | called by muse, mutect2, varscan2
- ADAM20P1 | n.977T>C | RNA (SNP) | VAF 70/201 reads (35%) | called by muse, mutect2, varscan2
- AP2A2 | c.67+6618C>T | Intron (SNP) | VAF 65/256 reads (25%) | catalogued as rs1031813470; called by muse, mutect2, varscan2
- BLACE | n.1390G>T | RNA (SNP) | VAF 61/182 reads (34%) | called by muse, mutect2, varscan2
- C5orf64 | n.512+51978C>A | Intron (SNP) | VAF 27/316 reads (9%) | called by muse, mutect2
- C8orf87 | n.103C>A | RNA (SNP) | VAF 70/328 reads (21%) | catalogued as rs1444305879; called by muse, mutect2, varscan2
- CHN1 | c.712+2667G>A | Intron (SNP) | VAF 59/253 reads (23%) | catalogued as rs1232128675; called by muse, mutect2, varscan2
- CSRP1 | c.412-1629G>A | Intron (SNP) | VAF 13/107 reads (12%) | called by muse, mutect2, varscan2
- CYP11B1 | c.239+175G>C | Intron (SNP) | VAF 28/234 reads (12%) | called by muse, mutect2, varscan2
- DCX | c.-22-580G>T | Intron (SNP) | VAF 36/141 reads (26%) | called by muse, mutect2, varscan2
- DIO3 | chr14:101560420 C>T | 5'Flank (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2, varscan2
- FAM131B | c.91-64C>T | Intron (SNP) | VAF 50/626 reads (8%) | catalogued as rs962766973; called by muse, mutect2
- FAM183BP | n.1058C>T | RNA (SNP) | VAF 49/473 reads (10%) | called by muse, mutect2, varscan2
- FMR1 | c.*95A>G | 3'UTR (SNP) | VAF 20/243 reads (8%) | catalogued as rs949966796; called by muse, mutect2
- GJB1 | c.*44C>G | 3'UTR (SNP) | VAF 13/101 reads (13%) | called by muse, mutect2
- GRAMD1B | c.-38G>A | 5'UTR (SNP) | VAF 12/137 reads (9%) | called by muse, mutect2
- GTF2IRD2P1 | n.2044G>T | RNA (SNP) | VAF 276/657 reads (42%) | called by muse, mutect2, varscan2
- GTF2IRD2P1 | n.2043G>A | RNA (SNP) | VAF 275/658 reads (42%) | called by muse, mutect2, varscan2
- HDAC8 | c.738-9984C>A | Intron (SNP) | VAF 14/172 reads (8%) | called by muse, mutect2
- HSP90AB3P | n.1075G>T | RNA (SNP) | VAF 42/372 reads (11%) | called by muse, mutect2, varscan2
- KIF26B | c.999+3218G>T | Intron (SNP) | VAF 71/270 reads (26%) | called by muse, mutect2, varscan2
- KIF5C | c.292-2199G>T | Intron (SNP) | VAF 15/44 reads (34%) | called by muse, mutect2, varscan2
- LAMP2 | c.1093+2507G>T | Intron (SNP) | VAF 24/276 reads (9%) | called by muse, mutect2
- LCOR | c.*2498A>G | 3'UTR (SNP) | VAF 14/175 reads (8%) | called by muse, mutect2
- LEPR | c.-159G>T | 5'UTR (SNP) | VAF 22/280 reads (8%) | called by muse, mutect2
- LINC01169 | n.284G>T | RNA (SNP) | VAF 23/167 reads (14%) | called by muse, mutect2, varscan2
- LINC01169 | n.285G>T | RNA (SNP) | VAF 23/167 reads (14%) | called by muse, mutect2, varscan2
- MACF1 | c.15832-10776G>C | Intron (SNP) | VAF 19/171 reads (11%) | catalogued as COSV57109540; called by muse, varscan2
- MIR4771-1 | chr2:87193447 G>T | 5'Flank (SNP) | VAF 14/104 reads (13%) | called by muse, mutect2, varscan2
- MSRB1 | c.205-22A>G | Intron (SNP) | VAF 69/152 reads (45%) | called by muse, mutect2, varscan2
- NOL4 | c.264+967C>G | Intron (SNP) | VAF 69/273 reads (25%) | called by muse, mutect2, varscan2
- NRXN2 | c.*14C>T | 3'UTR (SNP) | VAF 8/34 reads (24%) | catalogued as rs763821991, COSV55452609; called by muse, mutect2
- NUDT5 | c.*942T>C | 3'UTR (SNP) | VAF 15/104 reads (14%) | called by muse, mutect2, varscan2
- OR2U1P | n.494C>A | RNA (SNP) | VAF 8/79 reads (10%) | called by muse, mutect2
- PCDH11X | c.3144+24852C>A | Intron (SNP) | VAF 46/259 reads (18%) | catalogued as COSV53460863; called by muse, mutect2, varscan2
- PHKA2 | c.*41G>T | 3'UTR (SNP) | VAF 21/163 reads (13%) | called by muse, mutect2, varscan2
- PRR13 | c.-21+55A>G | Intron (SNP) | VAF 21/126 reads (17%) | called by muse, mutect2, varscan2
- RGS20 | c.510+1380G>C | Intron (SNP) | VAF 22/175 reads (13%) | catalogued as rs780622131, COSV52017389; called by muse, mutect2, varscan2
- SRRM2 | c.-187G>T | 5'UTR (SNP) | VAF 25/61 reads (41%) | called by muse, mutect2, varscan2
- SSPOP | n.2228C>T | RNA (SNP) | VAF 164/374 reads (44%) | catalogued as COSV50489693; called by muse, mutect2, varscan2
- TEX15 | chr8:30849020 G>C | 5'Flank (SNP) | VAF 86/367 reads (23%) | called by muse, mutect2, varscan2
- TINAG | c.624+261A>T | Intron (SNP) | VAF 25/186 reads (13%) | called by muse, mutect2, varscan2
- TMEM135 | c.*6199A>T | 3'UTR (SNP) | VAF 38/98 reads (39%) | called by muse, mutect2, varscan2
- TTC41P | n.211A>T | RNA (SNP) | VAF 56/156 reads (36%) | called by muse, varscan2
- VGLL4 | c.65-41487A>T | Intron (SNP) | VAF 48/196 reads (24%) | called by muse, mutect2, varscan2
- WT1 | chr11:32437912 G>A | 5'Flank (SNP) | VAF 11/66 reads (17%) | called by muse, mutect2, varscan2
- ZNF467 | chr7:149777634 G>C | 5'Flank (SNP) | VAF 15/105 reads (14%) | called by muse, mutect2, varscan2
